Somatic mutation profile of tumor specimen TCGA-AB-2811-03B (aliquot TCGA-AB-2811-03B-01W-0728-08) from TCGA case TCGA-AB-2811, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.5 years (29,766 days).
Specimen TCGA-AB-2811-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b12e942f-b6fa-47b3-ba28-6bbd439258ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2811-11B (Solid Tissue Normal), aliquot TCGA-AB-2811-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/287b1422-71c4-4dc8-8305-0d00a0e03760

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TEKT4 | c.1255A>G p.M419V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as COSV54622877; called by muse, mutect2, varscan2
- TKTL2 | c.120G>A p.T40= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV54917372; called by muse, mutect2, varscan2
- ZBTB26 | c.990C>T p.I330= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV101021010; called by muse, mutect2
